Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3854, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3854-01A (Primary Tumor).

Diagnosis:

This is a mucinous adenocarcinoma in I) with infiltration of the muscularis and vessels (G3, pT2, L1, V1) with free resection margins and free lymph nodes (locally R0, pN0, 0 of 12).

in II) a free anastomosis ring

and in III) fragments of a serrated adenoma with focally severe chromatin disorders in the sense of a high-risk type of [REDACTED]

Source: NCI Genomic Data Commons file 58bc6571-0be2-4f35-9a4d-fa7da9575e0b (TCGA-AA-3854.DA5AC5A8-184C-4D2F-B0C4-5D2E8E3B7580.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).